Somatic mutation profile of tumor specimen TCGA-CS-6186-01A (aliquot TCGA-CS-6186-01A-12D-2024-08) from TCGA case TCGA-CS-6186, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 58.4 years (21,321 days).
Specimen TCGA-CS-6186-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1684442f-5cf4-4e00-87b2-f275f903980a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-6186-10A (Blood Derived Normal), aliquot TCGA-CS-6186-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9105abc-8deb-4c74-a60f-622291cad941

The open-access MAF lists 50 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 2, Splice Site 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.2091C>G p.F697L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as COSV61251181, COSV61252017; called by muse, mutect2, varscan2
- ADGRV1 | c.16942C>T p.L5648F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67991513; called by muse, mutect2, varscan2
- ALG5 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs368291171; called by muse, mutect2, varscan2
- ANKRD1 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV63311125; called by muse, mutect2, varscan2
- ASAP1 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63046134, COSV63052276; called by muse, mutect2, varscan2
- ATP8B4 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376253325; called by muse, mutect2, varscan2
- CENPA | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as rs1306877972, COSV51982411, COSV51982620; called by muse, mutect2, varscan2
- DOCK5 | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs767750406, COSV52407633, COSV52409781; called by muse, mutect2, varscan2
- DYNC1I1 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs546629907, COSV61467244; called by muse, mutect2, varscan2
- EPN3 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs756351981, COSV52141989; called by muse, mutect2, varscan2
- FAM47B | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV61455815; called by muse, mutect2, varscan2
- G6PC2 | c.892T>G p.L298V | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56372852; called by muse, mutect2, varscan2
- GRIA1 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53615677; called by muse, mutect2, varscan2
- GUCY2C | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs756518777, COSV53791446; called by muse, mutect2, varscan2
- HLA-DMB | c.130A>C p.I44L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.036); catalogued as COSV66870901; called by muse, mutect2, varscan2
- HOXB5 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.144); catalogued as rs1332454676, COSV53313823, COSV99494570; called by mutect2, varscan2
- LAMA4 | c.2275C>G p.L759V (on ENST00000230538 / NM_001105206.3; = p.L752V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100037389, COSV57902171; called by muse, mutect2, varscan2
- LAMB1 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1258805799, COSV55968146; called by muse, mutect2, varscan2
- MAGEB16 | c.178A>T p.S60C | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV101303301, COSV67874292; called by muse, mutect2, varscan2
- MAMDC2 | c.505+1G>A p.X169_splice | Splice Site (SNP) | VAF 48/99 reads (48%) | catalogued as COSV65859685; called by muse, mutect2, varscan2
- MUC5B | c.13496C>T p.S4499F | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV101500553, COSV71594333; called by muse, mutect2, varscan2
- MYO5A | c.4384C>T p.R1462* | Nonsense Mutation (SNP) | VAF 58/132 reads (44%) | catalogued as COSV62556947; called by muse, mutect2, varscan2
- NLRP9 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs373989650, COSV60465731; called by mutect2, varscan2
- OR2AT4 | c.739A>T p.S247C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV59407432; called by muse, mutect2, varscan2
- OR4F6 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs761856071, COSV61027230; called by muse, mutect2, varscan2
- OR5F1 | c.301A>T p.M101L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV53547800; called by muse, mutect2, varscan2
- PAK6 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs752441056, COSV53046942; called by muse, mutect2
- PCDH12 | c.1875T>A p.D625E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51523310; called by muse, mutect2, varscan2
- PDE2A | c.2511G>A p.E837= | Splice Region (SNP) | VAF 28/65 reads (43%) | catalogued as rs772561675, COSV57811208; called by muse, mutect2, varscan2
- SELE | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as rs770008382, COSV60976449, COSV60977628; called by muse, mutect2, varscan2
- SH3TC2 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60466081; called by muse, mutect2, varscan2
- SLC23A2 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57777459; called by muse, mutect2, varscan2
- SPANXN2 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 136/156 reads (87%) | SIFT tolerated (0.85); PolyPhen benign (0.1); catalogued as rs782507654, COSV65127843, COSV65127901; called by muse, varscan2
- SPNS1 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs1280677156, COSV57955928; called by muse, mutect2, varscan2
- TENM2 | c.5677G>A p.V1893M (on ENST00000518659 / NM_001122679.2; = p.V1654M on NM_001080428.3) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1340235658, COSV69130801; called by muse, mutect2, varscan2
- TTC21A | c.3635G>C p.C1212S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56189288; called by muse, mutect2
- USH2A | c.5356C>T p.Q1786* | Nonsense Mutation (SNP) | VAF 138/336 reads (41%) | catalogued as CM149919, COSV56407919; called by muse, mutect2, varscan2
- RBMY1E | c.1373del p.P458Lfs*23 | Frame Shift Del (DEL) | VAF 28/141 reads (20%) | called by mutect2, pindel, varscan2
- ACSM4 | c.1500G>A p.S500= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs576957989, COSV68066651; called by muse, mutect2, varscan2
- CHST4 | c.300C>T p.A100= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs139260372, COSV58297884; called by muse, mutect2, varscan2
- GOLGA2 | c.1680G>A p.S560= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs373870855, COSV57854566; called by muse, mutect2, varscan2
- GPR55 | c.945G>A p.T315= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs750679484, COSV67407349; called by muse, mutect2, varscan2
- INTS6L | c.1434G>T p.G478= | Silent (SNP) | VAF 29/38 reads (76%) | catalogued as COSV66085438; called by muse, mutect2, varscan2
- KCNS3 | c.765G>A p.L255= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV58408252; called by muse, mutect2, varscan2
- MFSD13A | c.996C>T p.Y332= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as rs201561138, COSV53268591; called by muse, mutect2, varscan2
- MYH14 | c.1299G>A p.K433= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1231020006, COSV51826738; called by muse, mutect2, varscan2
- SLC8A2 | c.2319C>T p.F773= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs779551163, COSV99369736; called by muse, mutect2, varscan2
- SYNE3 | c.498G>A p.Q166= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV62081260; called by muse, mutect2, varscan2
- TCTE3 | c.234G>A p.L78= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV64656073; called by muse, mutect2, varscan2
- VSX1 | c.951T>G p.P317= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV65021869; called by muse, mutect2, varscan2
